PECGS case C083-000008 — USC PE-CGS: Optimizing Engagement of Hispanic Colorectal Cancer Patients in Cancer Genomic Characterization Studies (PECGS-COPECC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon.
https://portal.gdc.cancer.gov/cases/7ea00756-abeb-4a6d-8bf7-47d8ea943755

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 42 years; Year of birth: 1978; Education level: College Degree.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Descending colon; Age at diagnosis: 42.0 years (15,341 days); AJCC pathologic stage: Stage IIA; Progression or recurrence: no.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 0.75.

Biospecimens (2 samples)
- Sample C083-000008_Germline: Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample C083-000008_Tumor: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
